Somatic mutation profile of tumor specimen TCGA-21-1076-01A (aliquot TCGA-21-1076-01A-01D-1521-08) from TCGA case TCGA-21-1076, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.4 years (19,863 days).
Specimen TCGA-21-1076-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e16eeac6-9575-4b3c-9bc3-bd55dbed8dc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1076-11A (Solid Tissue Normal), aliquot TCGA-21-1076-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8af5dc9-2b72-4ba2-aa0d-31e5196de176

The open-access MAF lists 375 somatic variants for this specimen: 282 protein-altering or splice-affecting, 85 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 246, Silent 85, Nonsense Mutation 20, Frame Shift Del 7, Splice Site 5, RNA 5, Splice Region 2, 3'UTR 2, Intron 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 43/122 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV56644794; called by muse, mutect2, varscan2
- ADAM2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV55862796; called by muse, mutect2, varscan2
- ADAMTS12 | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61262000; called by muse, mutect2, varscan2
- ADAMTS16 | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV56998405; called by muse, mutect2, varscan2
- ADGRE1 | c.2405C>A p.A802D | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51678438; called by muse, varscan2
- ADGRV1 | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67979234, COSV67990460; called by muse, mutect2, varscan2
- AFG1L | c.1295T>C p.M432T | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV64556883; called by muse, mutect2, varscan2
- AKAP14 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV57630739; called by muse, mutect2
- AKAP4 | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62074928; called by muse, mutect2, varscan2
- ALDH8A1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.06); catalogued as rs141981819; called by muse, mutect2
- ALDH8A1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 21/198 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV55642976; called by muse, mutect2, varscan2
- AMBP | c.451T>C p.Y151H | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54324679; called by muse, mutect2, varscan2
- APEX2 | c.1386del p.L464Cfs*14 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as COSV100237847; called by mutect2, pindel, varscan2
- ARHGEF28 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV55263223; called by muse, mutect2, varscan2
- ARHGEF9 | c.5C>A p.T2K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.972); catalogued as COSV53641071; called by muse, mutect2
- ASXL1 | c.3343A>G p.S1115G | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV60114370; called by muse, mutect2, varscan2
- ATG7 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753893278, COSV61611102; called by muse, mutect2, varscan2
- BCAN | c.590T>A p.L197H | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.194); catalogued as COSV61258135; called by muse, mutect2
- BCHE | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52259515; called by muse, mutect2, varscan2
- BTK | c.1349+1G>T p.X450_splice | Splice Site (SNP) | VAF 70/445 reads (16%) | catalogued as CS022091, CS971634, COSV58122059; called by muse, mutect2, varscan2
- C14orf39 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV58783568; called by muse, mutect2, varscan2
- C1orf159 | c.420G>T p.G140= (on ENST00000379339 / NM_001330306.2; = p.G104= on NM_017891.5) | Splice Region (SNP) | VAF 6/37 reads (16%) | catalogued as COSV53882094; called by muse, mutect2, varscan2
- CACYBP | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100871610, COSV62881371; called by muse, mutect2
- CASS4 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV64387438; called by muse, mutect2, varscan2
- CCDC144A | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 13/129 reads (10%) | catalogued as COSV60700047; called by muse, mutect2, varscan2
- CCDC22 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV100873161; called by muse, mutect2, varscan2
- CCSER1 | c.1865G>T p.R622I | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1053213704, COSV61449106; called by muse, mutect2, varscan2
- CD300E | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60791097; called by muse, mutect2
- CEACAM20 | c.85G>C p.A29P | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57602472; called by muse, mutect2, varscan2
- CHD5 | c.2822C>A p.P941Q | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52418325; called by muse, mutect2, varscan2
- CHRNA5 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55139501; called by muse, mutect2
- CILP | c.3476G>A p.S1159N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs776934891, COSV56026142; called by muse, mutect2, varscan2
- CLCN6 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV56743485; called by muse, mutect2, varscan2
- CLDN2 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV61021035; called by muse, mutect2, varscan2
- CMIP | c.1709G>A p.G570D (on ENST00000537098 / NM_198390.2; = p.G476D on NM_030629.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV67699492; called by muse, mutect2, varscan2
- COL3A1 | c.3220G>T p.G1074C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1412698, COSV58584727; called by muse, mutect2, varscan2
- CORO2A | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs773618810, COSV59663934; called by muse, mutect2, varscan2
- CPS1 | c.602T>A p.I201N | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV51817268; called by muse, mutect2, varscan2
- CRABP1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as rs1265380738, COSV55116080; called by muse, mutect2, varscan2
- CRNKL1 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55638433; called by muse, mutect2, varscan2
- CSMD2 | c.877A>T p.N293Y | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53935059; called by muse, mutect2, varscan2
- CYBB | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV66085880; called by muse, mutect2
- DBF4 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55997946; called by muse, mutect2, varscan2
- DEFB116 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV68722309; called by muse, mutect2, varscan2
- DESI2 | c.522del p.A175Hfs*48 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as COSV99797991; called by mutect2, pindel, varscan2
- DGKD | c.2403T>A p.Y801* (on ENST00000264057 / NM_152879.3; = p.Y757* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/208 reads (11%) | catalogued as COSV51070943; called by muse, mutect2, varscan2
- DNAH5 | c.2936A>T p.E979V | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV54239503; called by muse, mutect2, varscan2
- DNAH9 | c.7345G>T p.A2449S | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.122); catalogued as COSV52362377; called by muse, mutect2, varscan2
- DOCK9 | c.1418T>A p.F473Y (on ENST00000376460 / NM_001366676.2; = p.F474Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as COSV59636457; called by muse, mutect2, varscan2
- DPCD | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64509667; called by muse, mutect2, varscan2
- DPPA5 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV64875809; called by muse, mutect2, varscan2
- DPYSL4 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs748333066, COSV58307708, COSV58308721; called by muse, mutect2, varscan2
- DTNA | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV52014921; called by muse, mutect2, varscan2
- EBF1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 49/271 reads (18%) | catalogued as COSV58187120; called by muse, mutect2, varscan2
- ECM2 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV60742008; called by muse, mutect2, varscan2
- EIF3C | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 120/1183 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59060731; called by muse, varscan2
- ENAM | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV68536568; called by muse, mutect2, varscan2
- ENPP4 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 11/335 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV58089571; called by muse, mutect2
- ENTHD1 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57322658, COSV57323545; called by muse, mutect2, varscan2
- EP400 | c.4042G>C p.V1348L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV57779077; called by muse, mutect2, varscan2
- EPHB1 | c.2593C>T p.R865W | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758204492, COSV67653431; called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.417A>T p.E139D | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV60549128; called by muse, mutect2, varscan2
- ERCC6L | c.2664G>T p.E888D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57819598; called by muse, mutect2, varscan2
- EYA4 | c.990A>T p.G330= (on ENST00000531901 / NM_001301013.1; = p.G324= on NM_004100.5) | Splice Region (SNP) | VAF 46/267 reads (17%) | catalogued as COSV62057109; called by muse, mutect2, varscan2
- EYS | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV60982434; called by muse, mutect2, varscan2
- FAM120C | c.2963G>A p.G988D | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV60260786; called by muse, mutect2
- FAM199X | c.843C>A p.S281R | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55434124; called by muse, mutect2
- FBXL18 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101212140; called by muse, mutect2
- FCN1 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.223); catalogued as COSV65662673; called by muse, mutect2, varscan2
- FGD3 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV61598831; called by muse, mutect2
- FMR1NB | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as rs142312123, COSV65071773, COSV65073207; called by muse, mutect2
- FRMD7 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV53748366; called by muse, mutect2
- FRMPD4 | c.3436C>G p.Q1146E | Missense Mutation (SNP) | VAF 59/528 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.137); catalogued as COSV66219225; called by muse, mutect2, varscan2
- FSHR | c.1482G>C p.W494C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58628920; called by muse, mutect2, varscan2
- GABRR2 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV68764262, COSV68765679; called by muse, mutect2, varscan2
- GBX1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1267465497, COSV52548208, COSV52549208; called by muse, mutect2
- GLRA2 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54344392, COSV99490558; called by muse, mutect2
- GOLGA4 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV62712157; called by muse, mutect2, varscan2
- GOLGB1 | c.5318T>C p.L1773P | Missense Mutation (SNP) | VAF 87/639 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV61468219; called by muse, mutect2, varscan2
- GPR12 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1368851574; called by muse, mutect2, varscan2
- GRB10 | c.1512C>A p.H504Q (on ENST00000398812; = p.H458Q on NM_001001549.3) | Missense Mutation (SNP) | VAF 29/449 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV60013200; called by muse, mutect2
- GRM3 | c.954C>A p.Y318* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV64468447, COSV64475846; called by muse, mutect2, varscan2
- GUCY1A1 | c.839C>G p.S280W | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56649234, COSV56653780; called by muse, mutect2, varscan2
- HCN4 | c.1217A>T p.H406L | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56085499; called by muse, mutect2, varscan2
- HDC | c.740C>A p.T247N | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767958947, COSV51075144; called by muse, mutect2
- HEATR5A | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 53/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66343500; called by muse, mutect2, varscan2
- HEATR6 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51747288; called by muse, mutect2, varscan2
- HELZ | c.2475G>T p.Q825H | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62379681; called by muse, mutect2, varscan2
- HOXD1 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs753497224; called by muse, mutect2
- HSD3B1 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV52491476; called by muse, mutect2, varscan2
- HSPA13 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.076); catalogued as COSV53466559; called by muse, mutect2
- HTATSF1 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as COSV54479973; called by muse, mutect2, varscan2
- ICAM3 | c.1592C>A p.T531K | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs372536524; called by muse, mutect2, varscan2
- IGBP1 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60556434; called by muse, mutect2
- IGHV1OR21-1 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 29/535 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777590073; called by muse, mutect2
- IGKV2D-29 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1241311912, COSV101534394; called by muse, mutect2, varscan2
- IL13RA2 | c.1139C>G p.T380R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54566219; called by muse, mutect2, varscan2
- IL22RA2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV51664030; called by muse, mutect2, varscan2
- ITGB1BP2 | c.913C>G p.H305D | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52138949; called by muse, mutect2
- ITIH1 | c.1765C>A p.L589M | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV56256812; called by muse, mutect2, varscan2
- ITIH6 | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as COSV54491402; called by muse, mutect2, varscan2
- ITIH6 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.035); catalogued as COSV54491417; called by muse, mutect2, varscan2
- ITPR2 | c.2939T>C p.I980T | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67272727; called by muse, mutect2, varscan2
- KANSL1L | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV55994414; called by muse, mutect2, varscan2
- KCND2 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV58592448; called by muse, mutect2, varscan2
- KCNV2 | c.1221C>A p.C407* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV66056922; called by muse, mutect2, varscan2
- KDM4B | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 70/509 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50236391; called by muse, mutect2, varscan2
- KIAA1210 | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68179885; called by muse, mutect2
- KLK2 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV57570230; called by muse, mutect2, varscan2
- LCE1B | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs754061206, COSV63980472; called by muse, mutect2, varscan2
- LGALS9C | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60196195; called by muse, mutect2
- LHCGR | c.1929C>A p.C643* | Nonsense Mutation (SNP) | VAF 45/323 reads (14%) | catalogued as COSV54300283; called by muse, mutect2, varscan2
- LIN7A | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV54018296; called by muse, mutect2, varscan2
- LRP10 | c.1477C>G p.P493A | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62078600; called by muse, mutect2, varscan2
- LRP12 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52631546; called by muse, mutect2, varscan2
- LRP1B | c.8966A>G p.Y2989C | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV67249362, COSV67263837; called by muse, mutect2, varscan2
- LRRC31 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1313242262; called by muse, mutect2
- LRRC47 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs1557642343, COSV65563113; called by muse, mutect2
- LRRC7 | c.1302G>T p.L434F (on ENST00000651989 / NM_001370785.2; = p.L401F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV50518359; called by muse, mutect2
- MAGEB16 | c.570T>A p.Y190* | Nonsense Mutation (SNP) | VAF 16/146 reads (11%) | catalogued as COSV67874246; called by muse, mutect2, varscan2
- MAGI1 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58333985, COSV58335219; called by muse, mutect2, varscan2
- MALL | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV55601000; called by muse, mutect2
- MAN2B1 | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV55473483, COSV99666855; called by muse, mutect2
- MDGA2 | c.2714G>C p.C905S (on ENST00000399232 / NM_001113498.2; = p.C607S on NM_182830.4) | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62103807; called by muse, mutect2, varscan2
- MMADHC | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57574167; called by muse, mutect2, varscan2
- MNDA | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV63740403, COSV63741562; called by muse, mutect2, varscan2
- MROH2B | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); catalogued as COSV68186910; called by muse, mutect2, varscan2
- MTMR8 | c.1460G>T p.S487I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV66395160; called by muse, mutect2, varscan2
- MYBL1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72919109; called by muse, mutect2
- MYH4 | c.3112-1G>T p.X1038_splice | Splice Site (SNP) | VAF 60/268 reads (22%) | catalogued as COSV55122485; called by muse, varscan2
- MYOM2 | c.2071G>C p.G691R | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50737282; called by muse, mutect2, varscan2
- NGF | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.605); catalogued as COSV65688323; called by muse, mutect2, varscan2
- NLRC4 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1426980819, COSV61593849; called by muse, mutect2, varscan2
- NOS3 | c.956+1G>T p.X319_splice | Splice Site (SNP) | VAF 82/378 reads (22%) | catalogued as COSV52492639; called by muse, mutect2, varscan2
- NPPB | c.288C>A p.Y96* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV64687739; called by muse, mutect2, varscan2
- NRDE2 | c.1991A>G p.N664S | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV62963968; called by muse, mutect2, varscan2
- NRXN3 | c.1589T>C p.V530A (on ENST00000335750 / NM_001330195.2; = p.V157A on NM_004796.6) | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59777480; called by muse, mutect2
- NTM | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV66186336; called by muse, mutect2, varscan2
- NTM | c.644T>G p.V215G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66186359; called by mutect2, varscan2
- NWD1 | c.3653C>G p.T1218S | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV60346699; called by muse, mutect2, varscan2
- OPHN1 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.122); catalogued as COSV62784554; called by muse, mutect2, varscan2
- OR11G2 | c.308A>T p.N103I | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62132762; called by muse, mutect2, varscan2
- OR1E1 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as COSV59459312; called by muse, mutect2, varscan2
- OR2T29 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV60771696; called by mutect2, varscan2
- OR52N5 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57699166; called by muse, mutect2
- OR5AC2 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62280007; called by muse, mutect2
- OR5H1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 95/461 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100641591, COSV63402924; called by muse, mutect2, varscan2
- OR5H14 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 160/679 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV71194262, COSV71194264; called by muse, mutect2, varscan2
- OR5I1 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV56888134; called by muse, mutect2, varscan2
- OR6K2 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV62743877; called by muse, mutect2, varscan2
- OSBPL8 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV53886320; called by muse, mutect2, varscan2
- P2RX2 | c.963C>A p.Y321* (on ENST00000343948 / NM_170683.4; = p.Y249* on NM_012226.5) | Nonsense Mutation (SNP) | VAF 44/310 reads (14%) | catalogued as COSV57685562; called by muse, mutect2, varscan2
- PACS2 | c.2050G>T p.V684L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.186); catalogued as COSV57655527; called by muse, mutect2
- PAN2 | c.3553G>A p.E1185K (on ENST00000425394 / NM_001127460.3; = p.E1181K on NM_014871.5) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV56263857; called by muse, mutect2
- PAPPA2 | c.1957C>A p.R653S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs370271956, COSV62778067; called by muse, mutect2, varscan2
- PCDH11X | c.1552C>A p.R518S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.932); catalogued as COSV53486709; called by muse, mutect2, varscan2
- PCDH11X | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53486739; called by muse, mutect2, varscan2
- PCDH15 | c.2909T>C p.V970A | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV57352707; called by muse, mutect2, varscan2
- PCDHA7 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs368032433, COSV65338759; called by muse, mutect2, varscan2
- PGRMC1 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54293194; called by muse, mutect2, varscan2
- PKHD1 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61886768; called by muse, mutect2, varscan2
- PLCG1 | c.3820C>T p.R1274* (on ENST00000373271 / NM_182811.2; = p.R1275* on NM_002660.3) | Nonsense Mutation (SNP) | VAF 10/174 reads (6%) | catalogued as COSV54821812; called by muse, mutect2
- PLEKHG4B | c.448G>A p.G150S (on ENST00000283426; = p.G506S on NM_052909.5) | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371569763; called by muse, mutect2, varscan2
- PLS3 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV56780629; called by muse, mutect2, varscan2
- PNLIPRP1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62612608; called by muse, mutect2, varscan2
- PPP1R3A | c.1721C>A p.T574N | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1471261440, COSV52887436; called by muse, mutect2, varscan2
- PPP4R3A | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV61505637; called by muse, mutect2, varscan2
- PPP4R4 | c.1365T>G p.D455E | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58556409; called by muse, mutect2
- PREX1 | c.4370G>A p.G1457D | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV64254284; called by muse, mutect2, varscan2
- PSG2 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 231/510 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV61545880; called by muse, mutect2, varscan2
- PTCHD1 | c.722A>T p.Q241L | Missense Mutation (SNP) | VAF 52/531 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV65061819; called by muse, mutect2
- PTP4A3 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61472319; called by muse, mutect2, varscan2
- PTPRN | c.2269A>G p.S757G | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV55350295; called by muse, mutect2, varscan2
- RASA1 | c.2406G>A p.M802I | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57192907, COSV57198698; called by muse, mutect2, varscan2
- RCBTB1 | c.1349A>T p.Y450F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51635707; called by muse, mutect2, varscan2
- RELN | c.5332T>C p.C1778R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59019480; called by muse, mutect2
- RFC4 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV56217365, COSV56217929; called by muse, mutect2, varscan2
- RINT1 | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as rs1184845991, COSV57559511; called by muse, mutect2, varscan2
- RIOK2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99299750; called by muse, mutect2
- RYR2 | c.6834G>T p.Q2278H | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV63698992; called by muse, mutect2, varscan2
- SAMD9 | c.1744A>G p.I582V | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1388047206, COSV66076704; called by muse, mutect2, varscan2
- SATB2 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53488960; called by muse, mutect2
- SCN10A | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV71861609; called by muse, mutect2, varscan2
- SCN1A | c.5632G>T p.E1878* (on ENST00000303395 / NM_001202435.3; = p.E1867* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/159 reads (10%) | catalogued as rs148703212, COSV57667838; called by muse, mutect2
- SCN3A | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV51809286; called by muse, mutect2, varscan2
- SDK2 | c.3394G>T p.V1132L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.475); catalogued as COSV66190552, COSV66191490, COSV66193653; called by muse, mutect2, varscan2
- SFTPA2 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 74/450 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs772763359, COSV64882452, COSV64882733; called by muse, mutect2, varscan2
- SIX4 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs745392790, COSV53670685; called by muse, mutect2, varscan2
- SLC4A4 | c.1174G>T p.E392* (on ENST00000264485 / NM_001098484.3; = p.E348* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV52630880; called by muse, mutect2, varscan2
- SLTM | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs751738807, COSV51055760; called by muse, mutect2
- SMARCA4 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV60802586, COSV60808993; called by muse, mutect2, varscan2
- SMOX | c.980A>T p.H327L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53866416; called by muse, mutect2, varscan2
- SNAI2 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV50079705; called by muse, mutect2, varscan2
- SPAST | c.1351A>G p.R451G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as CD147727, COSV59515965; called by muse, mutect2, varscan2
- SPATA31E1 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.647); catalogued as COSV57793540; called by muse, mutect2, varscan2
- SPATA31E1 | c.3917G>T p.R1306M | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57793550; called by muse, mutect2, varscan2
- SPEG | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56674945; called by muse, mutect2
- SPTBN1 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as rs1217112362; called by muse, mutect2
- STAT4 | c.2002G>C p.D668H | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61831160, COSV61832323; called by muse, mutect2, varscan2
- STRIP2 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV50806027; called by muse, mutect2, varscan2
- STYXL2 | c.2641G>T p.G881C | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs1206660067, COSV54807719; called by muse, varscan2
- SYNCRIP | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV62288604; called by muse, mutect2, varscan2
- TBCA | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1392871568, COSV60538717; called by muse, mutect2
- TBX18 | c.1372G>T p.V458L | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.282); catalogued as COSV63737497; called by muse, mutect2, varscan2
- TFEC | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as rs896136629, COSV55403841; called by muse, mutect2, varscan2
- TGM4 | c.549+1G>T p.X183_splice | Splice Site (SNP) | VAF 37/137 reads (27%) | catalogued as COSV56095184; called by muse, mutect2, varscan2
- TGM5 | c.1265C>A p.S422Y (on ENST00000220420 / NM_201631.4; = p.S340Y on NM_004245.4) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV55010889; called by muse, mutect2, varscan2
- TIGD4 | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV58550224; called by muse, mutect2, varscan2
- TLN1 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318866452, COSV59209658; called by muse, mutect2, varscan2
- TNC | c.3250G>C p.E1084Q | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV60787536, COSV60790096; called by muse, mutect2
- TNN | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53430657, COSV99511878; called by muse, mutect2, varscan2
- TNR | c.3860T>A p.V1287E | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54900305; called by muse, mutect2, varscan2
- TOX | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63844508, COSV63848528; called by muse, mutect2, varscan2
- TRAF6 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV61923091; called by muse, mutect2, varscan2
- TRAT1 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV55469702; called by muse, mutect2, varscan2
- TREM1 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565216476, COSV55149105; called by muse, mutect2
- TRIM50 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV60794596; called by muse, mutect2, varscan2
- TSHZ2 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs745999760, COSV61590076; called by muse, mutect2, varscan2
- TSHZ3 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 16/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53676746; called by muse, mutect2
- TTN | c.98646C>G p.F32882L (on ENST00000591111; = p.F25458L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/502 reads (4%) | PolyPhen benign (0.033); catalogued as COSV60196235; called by muse, mutect2
- TTN | c.52692G>C p.W17564C (on ENST00000591111; = p.W10140C on NM_003319.4) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | PolyPhen probably damaging (0.999); catalogued as COSV59915622, COSV60196260; called by muse, mutect2
- TTN | c.15733C>T p.Q5245* (on ENST00000591111; = p.Q4318* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/212 reads (12%) | catalogued as COSV60196330; called by muse, mutect2, varscan2
- TTN | c.11836T>G p.L3946V (on ENST00000591111; = p.L3900V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as COSV100624004; called by muse, mutect2
- UBE3A | c.2507G>A p.R836K | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV51668404; called by muse, mutect2, varscan2
- UGT2A3 | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV52361179, COSV99279749; called by muse, mutect2
- UGT2B4 | c.1314T>A p.Y438* | Nonsense Mutation (SNP) | VAF 30/160 reads (19%) | catalogued as rs772218125; called by muse, mutect2, varscan2
- UMPS | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 35/349 reads (10%) | catalogued as COSV51738139; called by muse, mutect2, varscan2
- USH2A | c.14232T>A p.H4744Q | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.462); catalogued as COSV56401308; called by muse, mutect2, varscan2
- USP33 | c.2011A>G p.S671G | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as rs1305626014, COSV62470420; called by muse, mutect2, varscan2
- UTRN | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV62341445; called by muse, mutect2
- UTRN | c.10270+1G>T p.X3424_splice | Splice Site (SNP) | VAF 21/113 reads (19%) | catalogued as COSV62310957; called by muse, mutect2, varscan2
- VSIG10 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100821280; called by muse, mutect2, varscan2
- WDR17 | c.2677G>T p.V893F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV54578703; called by muse, mutect2, varscan2
- ZBBX | c.952A>G p.M318V | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1344504797, COSV56795388; called by muse, mutect2, varscan2
- ZC4H2 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.103); catalogued as COSV62005000; called by muse, mutect2, varscan2
- ZFPM2 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV65874769; called by muse, mutect2, varscan2
- ZFPM2 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65874770; called by muse, mutect2, varscan2
- ZIM2 | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs762247047, COSV55640436; called by muse, mutect2
- ZNF112 | c.40G>A p.A14T (on ENST00000337401 / NM_001083335.2; = p.A8T on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61621237; called by muse, mutect2, varscan2
- ZNF208 | c.2849G>T p.C950F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68109833; called by muse, mutect2, varscan2
- ZNF222 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV51827625; called by muse, mutect2
- ZNF292 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV60543046; called by muse, mutect2, varscan2
- ZNF383 | c.887A>T p.Q296L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.303); catalogued as COSV61939616; called by muse, mutect2, varscan2
- ZNF462 | c.4553G>T p.R1518M | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52946005; called by muse, mutect2, varscan2
- ZNF594 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101280329, COSV68385834; called by muse, mutect2, varscan2
- ZNF704 | c.1118T>G p.V373G | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as COSV59925822; called by muse, mutect2, varscan2
- ZNF804A | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100167703, COSV56448862; called by muse, mutect2, varscan2
- ZNF804B | c.2068G>C p.G690R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV60827517, COSV60840429; called by muse, mutect2, varscan2
- ABCC5 | c.2268G>A p.M756I | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); called by muse, mutect2
- AMER3 | c.1789dup p.R597Kfs*14 | Frame Shift Ins (INS) | VAF 15/142 reads (11%) | called by mutect2, pindel, varscan2
- CALD1 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD46 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CLNS1A | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.052); called by muse, mutect2
- COL6A3 | c.8481C>A p.Y2827* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- DLC1 | c.4200del p.V1401* (on ENST00000276297 / NM_001348081.2; = p.V964* on NM_006094.5) | Frame Shift Del (DEL) | VAF 36/226 reads (16%) | called by mutect2, pindel, varscan2
- ELF2 | c.1460_1463del p.V487Efs*6 (on ENST00000379550 / NM_001331036.2; = p.V427Efs*6 on NM_006874.4) | Frame Shift Del (DEL) | VAF 21/118 reads (18%) | called by mutect2, pindel, varscan2
- FBXO32 | c.347_360del p.S116Lfs*38 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- GJD4 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 21/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- IBTK | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1D-17 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGKV2-24 | c.197del p.G66Afs*7 | Frame Shift Del (DEL) | VAF 62/310 reads (20%) | called by mutect2, varscan2
- KCNT1 | c.2845C>A p.R949S (on ENST00000488444; = p.R968S on NM_020822.3) | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- LAMC3 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, varscan2
- LILRB4 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MAGEA10 | c.1025A>T p.Q342L | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2
- MRTFA | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- NF1 | c.5828_5838del p.H1943Rfs*17 (on ENST00000358273 / NM_001042492.3; = p.H1922Rfs*17 on NM_000267.3) | Frame Shift Del (DEL) | VAF 14/131 reads (11%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.1022C>G p.T341S | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2
- PRPF38B | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 6/164 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); called by muse, mutect2
- QTRT2 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); called by muse, mutect2
- RIN3 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- RPLP0 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- SNAPC1 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.174); called by muse, mutect2
- SYCP1 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TJP3 | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2
- TRGV4 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP28 | c.2410G>C p.E804Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- WDR13 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- ZCCHC12 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.099); called by muse, mutect2
- ZNF324 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.03); called by muse, mutect2
- ZNF699 | c.981A>T p.R327S | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2
- ACSM2A | c.282C>T p.A94= (on ENST00000219054; = p.A15= on NM_001308169.2) | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV54587263; called by muse, mutect2, varscan2
- ADAM18 | c.15C>A p.L5= | Silent (SNP) | VAF 30/230 reads (13%) | catalogued as COSV55851086; called by muse, mutect2, varscan2
- ADAMTSL1 | c.48G>T p.L16= | Silent (SNP) | VAF 38/219 reads (17%) | catalogued as COSV52820036; called by muse, varscan2
- ADAMTSL1 | c.2727C>T p.I909= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1487116800, COSV65895286; called by muse, mutect2, varscan2
- ADAMTSL2 | c.243C>G p.S81= | Silent (SNP) | VAF 19/221 reads (9%) | called by muse, mutect2
- AEN | c.711G>T p.L237= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV60429829; called by muse, mutect2, varscan2
- ANKRD27 | c.879C>G p.L293= | Silent (SNP) | VAF 22/470 reads (5%) | catalogued as COSV60133713; called by muse, mutect2
- ANO2 | c.2322G>A p.V774= (on ENST00000356134 / NM_001278597.3; = p.V778= on NM_001278596.3) | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV59033382; called by muse, mutect2, varscan2
- ARFGAP1 | c.105G>A p.V35= | Silent (SNP) | VAF 61/301 reads (20%) | catalogued as COSV62263537; called by muse, mutect2, varscan2
- ASCC2 | c.1470C>T p.C490= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV57075191; called by muse, mutect2, varscan2
- ATP10B | c.3195T>A p.A1065= | Silent (SNP) | VAF 31/158 reads (20%) | catalogued as COSV59158769; called by muse, mutect2, varscan2
- BCHE | c.645A>G p.G215= | Silent (SNP) | VAF 32/236 reads (14%) | catalogued as COSV52259505; called by muse, mutect2, varscan2
- BMX | c.75T>C p.N25= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as rs759407744, COSV59591292, COSV59592342; called by muse, mutect2, varscan2
- CAMKK2 | c.1140A>T p.L380= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV61216288; called by muse, mutect2, varscan2
- CCDC33 | c.408C>T p.P136= | Silent (SNP) | VAF 44/224 reads (20%) | catalogued as COSV100351744, COSV58354904; called by muse, mutect2, varscan2
- CHD7 | c.2133G>A p.K711= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV71112820; called by mutect2, varscan2
- CNTN6 | c.138C>A p.V46= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV63180842; called by muse, mutect2, varscan2
- CSMD3 | c.9082T>C p.L3028= (on ENST00000297405 / NM_001363185.1; = p.L2859= on NM_052900.3) | Silent (SNP) | VAF 34/260 reads (13%) | catalogued as COSV52248139; called by muse, mutect2, varscan2
- DMD | c.1945C>A p.R649= | Silent (SNP) | VAF 24/267 reads (9%) | catalogued as CD067532, COSV104385820; called by muse, mutect2
- DSPP | c.1566T>C p.N522= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV56813326; called by muse, mutect2, varscan2
- EFEMP2 | c.327C>T p.C109= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV57260813; called by muse, mutect2, varscan2
- FERD3L | c.207G>T p.V69= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV51763499; called by muse, mutect2, varscan2
- FLNC | c.3477G>T p.R1159= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV57960153; called by muse, mutect2, varscan2
- GABBR1 | c.2034C>T p.Y678= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs758589287, COSV63541979; called by muse, mutect2, varscan2
- GPC4 | c.693C>T p.V231= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as rs1030694230, COSV63697857; called by muse, mutect2
- GPN1 | c.528C>T p.I176= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV53116175; called by muse, mutect2, varscan2
- HDC | c.741C>A p.T247= | Silent (SNP) | VAF 18/195 reads (9%) | catalogued as rs965590691, COSV51075051; called by muse, mutect2
- IGSF1 | c.2199C>A p.A733= | Silent (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- IL22RA1 | c.603C>A p.I201= | Silent (SNP) | VAF 6/113 reads (5%) | catalogued as COSV54629598; called by muse, mutect2
- INO80D | c.999A>T p.P333= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV68959534; called by muse, mutect2, varscan2
- KPNA4 | c.1305A>G p.L435= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as rs145152566; called by muse, mutect2, varscan2
- LRIT2 | c.1494C>T p.R498= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs140185624; called by muse, mutect2, varscan2
- LTF | c.732C>T p.D244= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs141357150, COSV99211663; called by muse, mutect2
- MAGEE1 | c.2520G>A p.Q840= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV63911195; called by muse, mutect2, varscan2
- MKRN3 | c.561A>C p.A187= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV58811041; called by muse, mutect2
- MOCOS | c.1890G>A p.Q630= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV54345366; called by muse, mutect2, varscan2
- MUC17 | c.5109C>A p.A1703= | Silent (SNP) | VAF 139/596 reads (23%) | catalogued as COSV60295996, COSV60300063; called by muse, mutect2, varscan2
- NAT16 | c.999C>T p.L333= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- NRXN1 | c.3882G>C p.V1294= | Silent (SNP) | VAF 14/203 reads (7%) | catalogued as COSV60510448, COSV60520176; called by muse, mutect2
- NTM | c.504T>C p.T168= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs932768205, COSV66186346, COSV66191564; called by muse, mutect2, varscan2
- NTRK1 | c.735A>G p.P245= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs771930428, COSV62327171; called by muse, mutect2
- NUDT18 | c.825C>A p.T275= | Silent (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- NUP133 | c.621G>A p.K207= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV54573486; called by muse, mutect2, varscan2
- OR1S2 | c.48A>G p.Q16= | Silent (SNP) | VAF 32/171 reads (19%) | catalogued as rs975870520, COSV100224217, COSV56919919; called by muse, mutect2, varscan2
- OR2L13 | c.261C>A p.G87= | Silent (SNP) | VAF 55/396 reads (14%) | catalogued as COSV63557127; called by muse, mutect2, varscan2
- OR4Q3 | c.618G>T p.V206= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV59179530; called by muse, mutect2, varscan2
- OR51D1 | c.366C>A p.A122= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV62914935; called by muse, mutect2, varscan2
- OR52I1 | c.456C>T p.V152= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as COSV56169240; called by muse, mutect2, varscan2
- OR5M1 | c.438T>C p.T146= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV73202279; called by muse, mutect2, varscan2
- OR8B12 | c.46T>C p.L16= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV60912285; called by muse, mutect2, varscan2
- ORC3 | c.99G>T p.G33= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV57642011; called by muse, mutect2, varscan2
- PA2G4 | c.300C>G p.L100= | Silent (SNP) | VAF 11/244 reads (5%) | called by muse, mutect2
- PAPPA | c.2880C>T p.C960= | Silent (SNP) | VAF 18/344 reads (5%) | catalogued as rs1266081085, COSV60287197; called by muse, mutect2
- PAX4 | c.810C>T p.A270= | Silent (SNP) | VAF 62/228 reads (27%) | catalogued as COSV58389992; called by muse, mutect2, varscan2
- PHLDB2 | c.3012G>A p.L1004= (on ENST00000393925 / NM_001134439.2; = p.L961= on NM_145753.2) | Silent (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- PNLIPRP1 | c.441G>T p.V147= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV62612601; called by muse, mutect2, varscan2
- PNPLA5 | c.954G>C p.L318= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as COSV53375561; called by muse, mutect2, varscan2
- PRDM1 | c.2235G>T p.V745= | Silent (SNP) | VAF 54/301 reads (18%) | catalogued as COSV64846016; called by muse, mutect2, varscan2
- PTPRJ | c.1335G>C p.P445= | Silent (SNP) | VAF 31/158 reads (20%) | catalogued as COSV69253398; called by muse, mutect2, varscan2
- RGS5 | c.105C>T p.D35= | Silent (SNP) | VAF 42/298 reads (14%) | catalogued as COSV58353513; called by muse, mutect2, varscan2
- RYR2 | c.7302C>A p.G2434= | Silent (SNP) | VAF 26/230 reads (11%) | catalogued as COSV63698995; called by muse, mutect2, varscan2
- SAMD15 | c.924T>G p.T308= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as COSV53627091; called by muse, mutect2
- SCN11A | c.723C>G p.V241= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV56574098; called by muse, mutect2
- SIRT5 | c.405C>T p.V135= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs760106683, COSV63081117; called by muse, mutect2, varscan2
- SLC6A18 | c.654G>T p.L218= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as COSV57252918; called by muse, mutect2, varscan2
- SPTB | c.2508G>A p.Q836= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV67633565; called by muse, mutect2, varscan2
- SRPX | c.582C>G p.P194= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV59440088; called by muse, mutect2
- STAB2 | c.1920C>G p.A640= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV66342903; called by muse, mutect2, varscan2
- TASP1 | c.879T>C p.C293= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as COSV61814353; called by muse, mutect2
- TBC1D23 | c.1149G>A p.Q383= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV100792727; called by muse, mutect2
- TBC1D23 | c.1638T>A p.R546= (on ENST00000394144 / NM_001199198.3; = p.R531= on NM_018309.5) | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV61369107; called by muse, varscan2
- TEKT3 | c.681G>T p.L227= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV58628623; called by muse, mutect2, varscan2
- TMCC2 | c.1333C>T p.L445= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV58005092; called by muse, mutect2, varscan2
- TMEM132D | c.2994G>A p.E998= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as COSV67161317; called by muse, mutect2, varscan2
- TRAT1 | c.288C>A p.A96= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV55469713; called by muse, mutect2, varscan2
- TRAV13-1 | c.111C>T p.S37= | Silent (SNP) | VAF 17/196 reads (9%) | catalogued as rs201830464; called by muse, mutect2
- TTN | c.99306T>C p.Y33102= (on ENST00000591111; = p.Y25678= on NM_003319.4) | Silent (SNP) | VAF 19/165 reads (12%) | catalogued as rs762295035, COSV60196194; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.94986A>G p.L31662= (on ENST00000591111; = p.L24238= on NM_003319.4) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs878926568; called by muse, mutect2, varscan2
- TTN | c.23937T>A p.S7979= (on ENST00000591111; = p.S7052= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV60196303; called by muse, mutect2, varscan2
- UNC13C | c.2244G>A p.E748= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- UNC93A | c.1308G>A p.P436= | Silent (SNP) | VAF 84/581 reads (14%) | catalogued as rs147514798; called by muse, varscan2
- ZHX2 | c.639A>G p.E213= | Silent (SNP) | VAF 44/253 reads (17%) | catalogued as COSV58715059; called by muse, mutect2, varscan2
- ZNF385D | c.120T>A p.P40= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV55765449; called by muse, mutect2, varscan2
- ZNF491 | c.624A>T p.T208= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- ZNF554 | c.321A>T p.S107= | Silent (SNP) | VAF 27/270 reads (10%) | catalogued as COSV57886405; called by muse, mutect2, varscan2
- AL590867.2 | n.114G>T | RNA (SNP) | VAF 49/335 reads (15%) | called by muse, mutect2, varscan2
- ARMC6 | c.*48G>C | 3'UTR (SNP) | VAF 16/78 reads (21%) | catalogued as COSV99523022; called by muse, mutect2, varscan2
- C3P1 | n.2345C>A | RNA (SNP) | VAF 155/984 reads (16%) | called by muse, varscan2
- FAM74A3 | n.303A>G | RNA (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- FCRL2 | c.884-72C>T | Intron (SNP) | VAF 30/189 reads (16%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*360G>T | 3'UTR (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99337091; called by muse, mutect2, varscan2
- SNORD116-29 | n.5C>T | RNA (SNP) | VAF 14/93 reads (15%) | catalogued as rs974377887; called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1337G>T | RNA (SNP) | VAF 32/142 reads (23%) | called by muse, mutect2, varscan2
